Gene-level copy-number profile of tumor specimen TCGA-DX-A8BH-01A from TCGA case TCGA-DX-A8BH, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 87.0 years (31,770 days).
Specimen TCGA-DX-A8BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.996ea84f-9401-4f64-9074-f600728b5c39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BH-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/551c0b89-5acd-44b1-bbcb-52eac88ebd30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 266; copy number 2: 20,572; copy number 3: 19,275; copy number 4: 15,636; copy number 5: 2,655; copy number 6: 772; copy number 7: 328; copy number 8: 8; copy number 9: 2; copy number 11: 88; copy number 13: 1; copy number 19: 19; copy number 20: 41; copy number 22: 10; copy number 33: 2; copy number 60: 10; copy number 62: 3; copy number 63: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BH-01A-11D-A37B-01): tumor purity 0.43, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–1): FOCAD.
- chr9:20,786,927–30,575,012, 120 genes (within-gene range 0–33) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,942 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:108,099,110–113,134,016, 142 genes, copy number 5–7 (broad region; genes not listed).
- chr3:79,411,714–79,470,827, 1 gene, copy number 63: AC117461.1.
- chr3:83,924,157–84,051,419, 3 genes, copy number 62: AC092825.1, SRRM1P2, AC117464.1.
- chr3:86,816,740–87,631,619, 10 genes, copy number 60: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6.
- chr3:88,601,061–90,030,495, 8 genes, copy number 5: NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr3:134,313,576–143,060,725, 157 genes, copy number 5 (broad region; genes not listed).
- chr3:154,272,546–154,539,309, 6 genes, copy number 5: DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1.
- chr3:170,448,639–170,860,993, 1 gene, copy number 8 (within-gene range 3–8): SLC7A14-AS1.
- chr3:170,653,846–170,870,208, 5 genes, copy number 8: AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1.
- chr3:181,952,343–182,052,270, 3 genes, copy number 6: LINC01206, RN7SKP265, AC012081.2.
- chr5:32,103,445–34,373,850, 44 genes, copy number 5–9: AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1.
- chr5:42,423,439–45,895,970, 61 genes, copy number 5 (broad region; genes not listed).
- chr7:9,614,978–10,779,944, 12 genes, copy number 5 (within-gene range 4–5): GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1.
- chr7:110,662,644–111,562,517, 1 gene, copy number 6 (within-gene range 4–6): IMMP2L.
- chr7:111,091,006–131,558,217, 336 genes, copy number 5–8 (broad region; genes not listed).
- chr7:132,086,266–141,052,409, 147 genes, copy number 5 (broad region; genes not listed).
- chr8:38,400,215–42,051,994, 69 genes, copy number 7 (broad region; genes not listed).
- chr8:47,260,878–145,066,685, 1,504 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:30,670,964–34,520,988, 103 genes, copy number 11–63 (within-gene range 3–63) (broad region; genes not listed).
- chr9:35,360,540–43,045,120, 242 genes, copy number 5–20 (broad region; genes not listed).
- chr16:19,555,240–23,596,316, 117 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:5,978,403–24,163,425, 970 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 266. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
